Somatic mutation profile of tumor specimen 0DDLQ1 from CCDI case PBBPAP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.7 years (269 days).
Specimen 0DDLQ1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d93f3c8-bba1-4dc9-adc6-4b617c80f4a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDLPF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14a66ffa-718f-4680-9a7a-30a2d7ba4d1c

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 3'UTR 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10 | c.847G>A p.E283K (on ENST00000398564; = p.E258K on NM_014629.4) | Missense Mutation (SNP) | VAF 86/680 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as rs758232476, COSV50642368, COSV50671598; called by muse, mutect2, varscan2
- FOXI3 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 24/850 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1390571066; called by muse, mutect2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 17/758 reads (2%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- WDFY3 | c.9497G>C p.R3166P | Missense Mutation (SNP) | VAF 22/664 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 48/710 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as rs1167537044; called by muse, mutect2
- FREM1 | c.1461C>T p.D487= | Silent (SNP) | VAF 22/700 reads (3%) | called by muse, mutect2
- HUWE1 | c.9585G>C p.V3195= | Silent (SNP) | VAF 67/591 reads (11%) | called by muse, mutect2, varscan2
- ABHD17C | c.-81C>T | 5'UTR (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 24/658 reads (4%) | called by muse, mutect2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
